Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72K, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72K-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

ICD-6-3

Carcinoma, renal cell
chromophobe type 8317/3
Site O Kidney NOS C64.9
9/8/13

Diagnosis:

A: Base of tumor, excision

- Renal cell carcinoma, chromophobe type
- Fuhrman grade 3 of 4

B: Left renal mass, partial nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, chromophobe type; see comment

Sarcomatoid features: None identified

Histologic grade (if applicable): Fuhrman grade 3 of 4

Tumor size (greatest dimension): 3.7 cm

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: Negative for malignancy

Gerota' s fascia: Negative for malignancy

Venous (large vessel): Not identified

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): Tumor involves inked surgical margin (B1)

Renal capsular margin (partial nephrectomy only): Negative, but close; tumor is < 1 mm from the inked capsular margin

Paranephric adipose tissue margin (partial nephrectomy only): Negative for malignancy

Adrenal gland: Not sampled

Lymph nodes: Not sampled

AJCC Staging: pT1a pNX

[page 2 of 2]
This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

Immunohistochemical stains are performed and demonstrate the tumor is diffusely positive for CK7, CD10, E-Cadherin, and CD117 while being negative for RCC and vimentin. This immunophenotype, combined with the histologic features, is most consistent with the chromophobe variant of renal cell carcinoma.

Clinical History:

-year-old male with a left renal mass.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "base of tumor." It one tan/gray soft tissue mass measuring 1.0 x 0.7 x 0.4 cm. The tissue is submitted in block A1,

Container B is additionally labeled "left renal mass." It holds a partial nephrectomy specimen weighing 34.2 grams and measuring 5.4 x 4.7 x 3.5 cm overall. The kidney parenchymal margin is inked in black and the capsule overlying the mass is inked blue. Sectioning reveals a fairly well circumscribed mass measuring 3.7 x 3.3 x 2.4 cm. The capsule overlying the mass appears to be intact. The cut surface of the mass is tan/pink and there appears to be a small amount of residual tan/white kidney at the parenchymal margin. The tumor is grossly 0.2 cm from the black inked parenchymal margin.

Block Summary:

B1-B3 - mass with black inked parenchymal margin
B4-B5 - mass with overlying blue inked capsule
B6 - additional sections of mass

NIHAA Discrepancy		✓

Source: NCI Genomic Data Commons file 61743638-9ef6-4250-985d-20056d919d1b (TCGA-UW-A72K.1BBCA936-0E8A-4485-A26E-EA998B326F54.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).